MMRF case MMRF_1584 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/15713a83-8a83-491e-9b6d-52538a3e8478

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 44.0 years (16,063 days); ISS stage: II; Days to last known disease status: 7 days; Days to last follow up: 7 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 11 days; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 32 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 7.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 2.62 µkat/L.
- Calcium 1.9 mmol/L.
- Beta 2 Microglobulin 4.8 µg/mL.
- Immunoglobulin G 72.7 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL.
- M Protein 5.2 g/dL.
- Immunoglobulin A 0.26 g/L.
- Hemoglobin 6.2 mmol/L.
- Immunoglobulin M 0.19 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL.
- Leukocytes 8.1 ×10⁹/L.
- Glucose 7.92 mmol/L.
- Total Protein 11.5 g/dL.
- Albumin 25 g/L.
- Blood Urea Nitrogen 6.43 mmol/L.
- Platelets 182 ×10⁹/L.
- Absolute Neutrophil 6.72 ×10⁹/L.
- Creatinine 69.8 µmol/L.

Other clinical attributes
- Day 7: Weight: 65 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1584_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 7 days.
